Somatic mutation profile of tumor specimen C3L-06806-54 (aliquot CPT0394990002) from CPTAC case C3L-06806, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 71.4 years (26,075 days).
Specimen C3L-06806-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfde7e9a-8c7c-451c-beb3-c37300d4324b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06806-51 (Buccal Cell Normal), aliquot CPT0395090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7e6f6de-8659-42d5-bf7b-db56c089e4e9

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIRAS2 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs930935634, COSV65370689; called by muse, mutect2, varscan2
- NPM1 | c.867_868insAGGC p.W290Rfs*10 | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | catalogued as COSV51542908, COSV51543245, COSV51546408, COSV51550939, COSV51554851, COSV51559013, COSV51576311; called by mutect2, pindel, varscan2
- ZNF502 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56073114, COSV99939755; called by muse, mutect2
